Somatic mutation profile of tumor specimen TCGA-AJ-A2QK-01A (aliquot TCGA-AJ-A2QK-01A-11D-A18P-09) from TCGA case TCGA-AJ-A2QK, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 65.6 years (23,945 days).
Specimen TCGA-AJ-A2QK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20a07707-592d-481a-a8a0-b3f803fd00be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AJ-A2QK-10A (Blood Derived Normal), aliquot TCGA-AJ-A2QK-10A-01D-A18P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/710f756e-f37b-49e7-a3ce-0f03b424757f

The open-access MAF lists 77 somatic variants for this specimen: 53 protein-altering or splice-affecting, 21 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 21, Nonsense Mutation 6, RNA 3, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.9023G>A p.R3008H | Missense Mutation (SNP) | VAF 13/24 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs587781894, CM092589, COSV53726175, COSV53741856; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.1647T>A p.N549K | Missense Mutation (SNP) | VAF 32/69 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913476, COSV60638757, COSV60639738; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 32/59 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AMER3 | c.589C>T p.R197* | Nonsense Mutation (SNP) | VAF 3/15 reads (20%) | catalogued as rs1553491167, COSV58468551; called by muse, mutect2
- BTBD7 | c.1978C>T p.R660* | Nonsense Mutation (SNP) | VAF 3/29 reads (10%) | catalogued as rs1477522684, COSV100597823; called by muse, mutect2
- CCN1 | c.20G>T p.R7M | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.058); catalogued as COSV101486127; called by muse, mutect2, varscan2
- CCT6A | c.1485G>T p.W495C | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV51905091; called by muse, mutect2, varscan2
- CDH23 | c.7256C>A p.T2419K | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as COSV99820853; called by muse, mutect2, varscan2
- CFAP20DC | c.385C>T p.R129C (on ENST00000482387 / NM_001351530.2; = p.R4C on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as rs545378264, COSV55916221; called by muse, mutect2, varscan2
- CPNE1 | c.136C>T p.R46W (on ENST00000352393; = p.R51W on NM_003915.5) | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1329217194, COSV58293159; called by muse, mutect2, varscan2
- FLG2 | c.5157G>C p.R1719S | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101165849; called by muse, mutect2, varscan2
- FNDC4 | c.692C>A p.T231N | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as rs1318792399, COSV99253894; called by muse, mutect2, varscan2
- FZD3 | c.1970G>A p.R657Q | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.596); catalogued as rs776375064, COSV99528107; called by muse, mutect2, varscan2
- GZMB | c.683G>C p.R228P | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.481); catalogued as COSV53541839, COSV99362320; called by muse, mutect2, varscan2
- H2AC20 | c.337C>T p.Q113* | Nonsense Mutation (SNP) | VAF 31/80 reads (39%) | catalogued as COSV100479867; called by muse, mutect2, varscan2
- JAK1 | c.2554+2T>C p.X852_splice | Splice Site (SNP) | VAF 6/48 reads (13%) | catalogued as COSV100691690; called by muse, mutect2, varscan2
- KCNH8 | c.2070G>T p.M690I | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100109715; called by muse, mutect2, varscan2
- KCNIP4 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.035); catalogued as COSV100749394; called by mutect2, varscan2
- KLKB1 | c.755A>G p.Q252R | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.543); catalogued as COSV99249940; called by muse, mutect2, varscan2
- KMT2A | c.11222G>A p.R3741Q | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.819); catalogued as rs1342425133, COSV63284570; called by muse, mutect2, varscan2
- LAMB4 | c.992C>T p.S331L | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs1178892859, COSV99222997; called by muse, mutect2
- LIN9 | c.1040C>A p.P347H (on ENST00000366808 / NM_001270410.2; = p.P292H on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100067421; called by muse, mutect2
- LRP1 | c.12389T>A p.L4130Q | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV99675753; called by muse, mutect2, varscan2
- LRRK1 | c.4442G>T p.R1481L | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99439768; called by muse, mutect2, varscan2
- MTRR | c.354T>G p.Y118* (on ENST00000264668; = p.Y91* on NM_002454.3 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 20/84 reads (24%) | catalogued as COSV99241681; called by muse, mutect2, varscan2
- MUC5B | c.2728C>T p.R910C | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs375892324; called by muse, mutect2, varscan2
- NOTCH3 | c.4630C>T p.R1544C | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV99657152; called by muse, mutect2, varscan2
- NT5C3A | c.266G>A p.S89N (on ENST00000610140 / NM_001374335.1; = p.S55N on NM_016489.13) | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54237854; called by muse, mutect2, varscan2
- OR5B2 | c.859G>T p.V287F | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as rs1351143246, COSV100222876; called by muse, mutect2
- OSBPL1A | c.1165A>G p.M389V | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV100111755; called by muse, mutect2, varscan2
- PCDHA5 | c.1757C>T p.A586V | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.021); catalogued as rs138704270, COSV100972263; called by muse, mutect2
- PIK3CG | c.2275G>A p.V759I | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs765080806, COSV63245292; called by muse, mutect2, varscan2
- PKHD1 | c.1115T>G p.F372C | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100583040, COSV61894993; called by muse, mutect2, varscan2
- PLK4 | c.2056T>A p.Y686N | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99584642; called by muse, mutect2, varscan2
- POU5F1 | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs762875743, COSV52564715, COSV99462974; called by muse, mutect2, varscan2
- PPP2R1A | c.770G>T p.W257L | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV59042219, COSV59042372, COSV59048123; called by muse, mutect2, varscan2
- PRPF18 | c.43G>C p.V15L | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100187078; called by muse, mutect2
- PTEN | c.37A>G p.K13E | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as CM132262, COSV64289702, COSV64295241, COSV64304710; called by muse, mutect2, varscan2
- PTEN | c.83T>C p.I28T | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1355570425, COSV100911169, COSV64296071, COSV64296742; called by muse, mutect2, varscan2
- RAP1GAP2 | c.605T>G p.L202R | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.053); catalogued as COSV99623131; called by muse, mutect2, varscan2
- RUFY4 | c.1240G>T p.E414* | Nonsense Mutation (SNP) | VAF 9/18 reads (50%) | catalogued as COSV100723058, COSV100723088; called by muse, mutect2, varscan2
- RUNX1T1 | c.1712C>T p.T571M (on ENST00000265814 / NM_001198628.1; = p.T544M on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.985); catalogued as rs1422541659, COSV99751894; called by muse, mutect2, varscan2
- SCO2 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777154604, COSV52687259; called by muse, mutect2, varscan2
- SETD5 | c.1666G>T p.E556* | Nonsense Mutation (SNP) | VAF 19/65 reads (29%) | catalogued as COSV100200578; called by muse, mutect2, varscan2
- SLC5A2 | c.505G>C p.A169P | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555495710, COSV100392933, COSV57892238; called by muse, mutect2, varscan2
- SORBS2 | c.1298A>G p.N433S | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99510870; called by muse, mutect2, varscan2
- SPRTN | c.238A>G p.S80G | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as COSV99149741; called by muse, mutect2
- TCL1B | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs766229714, COSV100525767, COSV61552345; called by muse, mutect2, varscan2
- TOGARAM1 | c.4566C>A p.D1522E | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs567842372, COSV100818026; called by muse, mutect2, varscan2
- ZNF599 | c.913C>T p.H305Y | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100251117; called by muse, mutect2, varscan2
- ZNF705A | c.98G>A p.R33K | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV100828306; called by muse, mutect2, varscan2
- ZNF772 | c.73-2A>G p.X25_splice | Splice Site (SNP) | VAF 5/87 reads (6%) | catalogued as COSV100582825; called by muse, mutect2
- ZNF780A | c.548A>C p.H183P | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100575078; called by muse, mutect2, varscan2
- BPIFB4 | c.462T>G p.P154= | Silent (SNP) | VAF 10/80 reads (13%) | catalogued as COSV100971518; called by muse, mutect2, varscan2
- CCL5 | c.9C>A p.V3= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs1309188112; called by muse, mutect2, varscan2
- CHL1 | c.1164T>C p.F388= (on ENST00000397491 / NM_001253387.1; = p.F404= on NM_006614.4) | Silent (SNP) | VAF 22/86 reads (26%) | catalogued as COSV99851145; called by muse, mutect2, varscan2
- CNTN1 | c.1158C>T p.A386= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs74549636, COSV100751358; called by muse, varscan2
- COL9A1 | c.345G>A p.T115= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs777003491, COSV61831132, COSV61838372; called by muse, mutect2
- CTSO | c.492G>C p.S164= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV101467853; called by muse, mutect2, varscan2
- ECEL1 | c.1032G>T p.L344= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV100458701; called by muse, mutect2, varscan2
- FANCA | c.123G>A p.Q41= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as rs1459251575, COSV101224760; called by muse, mutect2, varscan2
- FLT4 | c.4035G>A p.E1345= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs754829541, COSV99986986; called by muse, mutect2, varscan2
- HACL1 | c.27C>T p.R9= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV100329576; called by muse, mutect2, varscan2
- IQSEC3 | c.2748G>A p.T916= (on ENST00000538872 / NM_001170738.2; = p.T613= on NM_015232.1) | Silent (SNP) | VAF 25/93 reads (27%) | catalogued as rs1299410789, COSV58292231; called by muse, mutect2
- JAKMIP3 | c.477C>T p.S159= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as rs751033443, COSV100059131; called by muse, mutect2, varscan2
- KIF25 | c.870G>A p.A290= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as rs371921249; called by muse, mutect2, varscan2
- LGR6 | c.510C>T p.D170= (on ENST00000367278 / NM_001017403.1; = p.D118= on NM_021636.3) | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as rs373499034; called by muse, mutect2
- NPFFR2 | c.1194C>T p.L398= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV58155350; called by muse, mutect2, varscan2
- PGM5 | c.978A>G p.P326= | Silent (SNP) | VAF 53/172 reads (31%) | catalogued as rs149148537, COSV101123434; called by muse, mutect2, varscan2
- PSAPL1 | c.1092T>C p.R364= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV100040484; called by muse, mutect2
- RASGRP4 | c.531C>G p.G177= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV99498576; called by muse, mutect2, varscan2
- SACS | c.789C>T p.N263= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs771920263, COSV66538577; ClinVar: likely benign; called by muse, mutect2, varscan2
- SIPA1L3 | c.2202G>A p.P734= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as rs774240682, COSV55910932, COSV99728705; called by muse, mutect2, varscan2
- ZNF804B | c.4005A>C p.L1335= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV100303714; called by muse, mutect2
- AGAP7P | n.1703C>T | RNA (SNP) | VAF 40/310 reads (13%) | catalogued as rs370476894; called by muse, mutect2, varscan2
- HERC2P3 | n.2241T>C | RNA (SNP) | VAF 16/106 reads (15%) | called by muse, mutect2
- MIR770 | n.88G>A | RNA (SNP) | VAF 11/29 reads (38%) | called by muse, mutect2, varscan2
